Somatic mutation profile of tumor specimen TCGA-BG-A0M4-01A (aliquot TCGA-BG-A0M4-01A-11W-A10C-09) from TCGA case TCGA-BG-A0M4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,090 days).
Specimen TCGA-BG-A0M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 483ed4f9-d432-4bfe-bfbe-d405a76a2cc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M4-10A (Blood Derived Normal), aliquot TCGA-BG-A0M4-10A-02W-A10C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5efa62c-b316-4299-a831-6b87fcc7abe8

The open-access MAF lists 684 somatic variants for this specimen: 524 protein-altering or splice-affecting, 145 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 379, Silent 145, Frame Shift Del 97, Nonsense Mutation 16, Frame Shift Ins 12, Splice Site 9, Intron 8, Splice Region 6, In Frame Del 3, 3'Flank 3, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs121908637, CM900032; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATM | c.9139C>T p.R3047* | Nonsense Mutation (SNP) | VAF 100/442 reads (23%) | catalogued as rs121434219, CM960114, COSV53724126; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CRB1 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 91/339 reads (27%) | catalogued as rs114342808, CM082582, COSV66328638, COSV66328719; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 54/387 reads (14%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 36/158 reads (23%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 34/119 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV55882681; called by muse, mutect2, varscan2
- PPARG | c.556del p.S186Vfs*47 (on ENST00000287820 / NM_015869.5; = p.S156Vfs*47 on NM_005037.7) | Frame Shift Del (DEL) | VAF 43/411 reads (10%) | catalogued as rs587776687; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 288/409 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 122/315 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3893A>G p.Y1298C | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55285889; called by muse, mutect2, varscan2
- ABCB1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199551851, COSV55945290, COSV55947749; called by muse, mutect2, varscan2
- ABCB6 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.555); catalogued as rs1185355342, COSV54692982; called by muse, mutect2
- ABI3BP | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV52528575; called by muse, mutect2, varscan2
- AC008397.2 | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53204732; called by muse, mutect2
- AC131160.1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57699952; called by muse, mutect2, varscan2
- ACAN | c.4927C>T p.P1643S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV61355974; called by muse, mutect2, varscan2
- ACKR1 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63671718; called by muse, mutect2, varscan2
- ACSM2A | c.1537T>C p.S513P (on ENST00000219054; = p.S434P on NM_001308169.2) | Missense Mutation (SNP) | VAF 194/582 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1362083893, COSV54582307; called by muse, mutect2, varscan2
- ACTN3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs999104173, COSV72207534; called by muse, mutect2, varscan2
- ACVR1C | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54643794; called by muse, mutect2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 36/294 reads (12%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADGRL1 | c.3663A>G p.P1221= (on ENST00000340736 / NM_001008701.3; = p.P1216= on NM_014921.5) | Splice Region (SNP) | VAF 55/161 reads (34%) | catalogued as COSV61563632; called by muse, mutect2, varscan2
- ADPGK | c.674A>G p.H225R | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61173329; called by muse, mutect2
- AFF2 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53977095, COSV99667005; called by muse, mutect2, varscan2
- AFF2 | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs149966195, COSV53977124, COSV53985327; called by muse, varscan2
- AKAP6 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV55205367; called by muse, mutect2, varscan2
- AL136295.1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759491065, COSV55778221; called by muse, varscan2
- ALDOA | c.967A>G p.T323A (on ENST00000642816 / NM_001243177.4; = p.T269A on NM_184041.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.822); catalogued as COSV57632005; called by muse, mutect2
- ANKRD13C | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV52029157; called by muse, varscan2
- ANKRD6 | c.1151del p.P384Hfs*21 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | catalogued as rs1293318031; called by mutect2, pindel, varscan2
- ANO6 | c.864-2A>G p.X288_splice | Splice Site (SNP) | VAF 23/469 reads (5%) | catalogued as rs1173340840, COSV57657031; called by muse, mutect2
- AP3M2 | c.1073T>C p.M358T | Missense Mutation (SNP) | VAF 126/454 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV51527638; called by muse, mutect2, varscan2
- APEX2 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775937817, COSV58188441; called by muse, mutect2, varscan2
- ARAP1 | c.3643A>G p.R1215G (on ENST00000393609 / NM_001040118.2; = p.R970G on NM_015242.4) | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV61989411; called by muse, mutect2, varscan2
- ARAP1 | c.721del p.A241Pfs*5 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as COSV61996073; called by mutect2, pindel, varscan2
- ARFGEF1 | c.3449T>C p.V1150A | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV51602641; called by muse, varscan2
- ARHGAP11A | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV64380582; called by muse, mutect2, varscan2
- ARHGAP20 | c.2737A>G p.S913G | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV52806766; called by muse, mutect2, varscan2
- ARHGAP21 | c.5104A>G p.T1702A | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57602280; called by muse, mutect2, varscan2
- ARHGEF11 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs750442493, COSV63810410; called by muse, mutect2, varscan2
- ARHGEF2 | c.605T>C p.M202T (on ENST00000361247 / NM_001162383.2; = p.M174T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV58106613; called by muse, mutect2, varscan2
- ARID5A | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV62590730; called by muse, mutect2, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARNTL2 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53823458; called by muse, mutect2
- ASB5 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs545829322, COSV56668638; called by muse, mutect2, varscan2
- ASB7 | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.945); catalogued as rs1368765268, COSV100235384; called by muse, mutect2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 16/149 reads (11%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG13 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1274241166, COSV56317490; called by muse, mutect2
- ATG2A | c.3604G>A p.G1202S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV65965861; called by muse, mutect2, varscan2
- ATP8B4 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52709392; called by muse, mutect2, varscan2
- ATP9B | c.484T>A p.F162I | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56946188; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- BIRC6 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1177083040, COSV70195605; called by muse, mutect2, varscan2
- C2orf16 | c.3326C>A p.P1109H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62673824; called by muse, mutect2, varscan2
- C3orf20 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs186405280; called by muse, mutect2
- CACNA1F | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as CM139713, COSV59903093; called by muse, mutect2
- CACNA1S | c.5578C>T p.Q1860* | Nonsense Mutation (SNP) | VAF 19/240 reads (8%) | catalogued as COSV62936292; called by muse, mutect2
- CACNA1S | c.3233A>G p.N1078S | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV62936298; called by muse, mutect2, varscan2
- CACNA2D1 | c.2583G>A p.M861I (on ENST00000356253 / NM_001366867.1; = p.M849I on NM_000722.4) | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV62372880, COSV62375405; called by muse, mutect2, varscan2
- CAD | c.6190C>T p.R2064C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023698, COSV53029560; called by muse, mutect2, varscan2
- CAMK2G | c.1024-1G>A p.X342_splice (on ENST00000423381 / NM_001367518.1; = p.X352_splice on NM_172170.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 14/107 reads (13%) | catalogued as COSV59480073; called by muse, mutect2, varscan2
- CAP2 | c.215A>C p.E72A | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.054); catalogued as COSV57730056; called by muse, mutect2, varscan2
- CASZ1 | c.2221T>C p.S741P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV59732198; called by muse, mutect2, varscan2
- CATSPERD | c.218del p.F73Sfs*26 | Frame Shift Del (DEL) | VAF 75/281 reads (27%) | catalogued as rs1305833783; called by mutect2, pindel, varscan2
- CBR1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs370632546; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 64/316 reads (20%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC15 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 39/388 reads (10%) | catalogued as rs565045511, COSV61080264; called by muse, mutect2, varscan2
- CCDC38 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 12/250 reads (5%) | catalogued as COSV60182234; called by muse, mutect2
- CD163L1 | c.3745C>T p.R1249C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs142773410; called by muse, mutect2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 33/298 reads (11%) | catalogued as rs781937995, COSV99163893; called by mutect2, varscan2
- CDCA2 | c.2821A>G p.T941A | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs1298526499, COSV57944416; called by muse, mutect2
- CDH7 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV59881631; called by muse, mutect2, varscan2
- CELSR1 | c.4006G>A p.V1336M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV53083748; called by muse, mutect2, varscan2
- CEP85L | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs185836271, COSV63820782; called by muse, mutect2
- CERS5 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV58188450; called by muse, mutect2, varscan2
- CFAP36 | c.935C>A p.T312K | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.323); catalogued as COSV55401834; called by muse, mutect2, varscan2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CHI3L2 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 241/660 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV63873350; called by muse, mutect2, varscan2
- CHL1 | c.1510G>A p.A504T (on ENST00000397491 / NM_001253387.1; = p.A520T on NM_006614.4) | Missense Mutation (SNP) | VAF 134/560 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV56586820; called by muse, mutect2, varscan2
- CLCA1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393276972, COSV52325123; called by muse, mutect2, varscan2
- CLEC7A | c.635C>T p.T212I (on ENST00000304084 / NM_197947.3; = p.T166I on NM_022570.5) | Missense Mutation (SNP) | VAF 18/610 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV53721176; called by muse, mutect2
- CLOCK | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as COSV59400459; called by muse, mutect2, varscan2
- CLTC | c.4301G>A p.R1434H | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52244917; called by muse, mutect2, varscan2
- CNDP1 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750904832, COSV62593178, COSV62594471; called by muse, mutect2, varscan2
- CNOT1 | c.3362C>T p.T1121M | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1277326354, COSV55313058; called by muse, mutect2, varscan2
- COL12A1 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 10/309 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59389732; called by muse, mutect2
- COL15A1 | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV66641427; called by muse, mutect2, varscan2
- COL19A1 | c.166+2T>C p.X56_splice | Splice Site (SNP) | VAF 36/109 reads (33%) | catalogued as COSV59565592; called by muse, mutect2, varscan2
- COX7C | c.124T>G p.C42G | Missense Mutation (SNP) | VAF 72/356 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV56030487; called by muse, mutect2, varscan2
- CPA6 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 172/637 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52721030; called by muse, mutect2, varscan2
- CPXM2 | c.1979T>C p.I660T | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53856320; called by muse, mutect2, varscan2
- CSE1L | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 32/1124 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.519); catalogued as COSV53700407; called by muse, mutect2
- CSMD1 | c.10403A>G p.Q3468R (on ENST00000520002; = p.Q3467R on NM_033225.6) | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV59282988; called by muse, mutect2, varscan2
- CSMD2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV53880581; called by muse, mutect2, varscan2
- CSMD3 | c.5749A>G p.R1917G (on ENST00000297405 / NM_001363185.1; = p.R1813G on NM_052900.3) | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV52105526; called by muse, mutect2, varscan2
- CSRNP1 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56187229; called by muse, mutect2, varscan2
- CTCFL | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs143392924, COSV54770842; called by muse, mutect2, varscan2
- CUL2 | c.1664G>T p.W555L | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66078356; called by muse, mutect2, varscan2
- CXADR | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1354395480, COSV53027904; called by muse, mutect2, varscan2
- CXCL3 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs759175981, COSV56017482; called by muse, mutect2, varscan2
- CYLC2 | c.747del p.D250Mfs*106 | Frame Shift Del (DEL) | VAF 80/663 reads (12%) | catalogued as COSV100872458; called by mutect2, pindel, varscan2
- CYP46A1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201296209, COSV55893072; called by muse, mutect2, varscan2
- DAOA | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 37/509 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV61601615; called by muse, mutect2
- DCAF1 | c.4200A>T p.E1400D | Missense Mutation (SNP) | VAF 74/609 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.006); catalogued as COSV60040654; called by mutect2, varscan2
- DCLRE1A | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63748181; called by muse, mutect2, varscan2
- DDX27 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65628986; called by muse, mutect2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs766714372; called by mutect2, varscan2
- DGKD | c.1906G>A p.A636T (on ENST00000264057 / NM_152879.3; = p.A592T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs748845678, COSV51033332; called by muse, mutect2, varscan2
- DHRS7B | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV60887348; called by muse, mutect2, varscan2
- DIS3L2 | c.1984A>G p.T662A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56048468; called by muse, varscan2
- DISP1 | c.4202C>T p.S1401L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52654754; called by muse, mutect2
- DNAH17 | c.8576C>T p.T2859I | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs774419226, COSV101103720; called by muse, mutect2, varscan2
- DNAH2 | c.3763C>A p.L1255M | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV66716454; called by muse, mutect2, varscan2
- DNAH8 | c.2282A>G p.N761S | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV59425604; called by muse, mutect2, varscan2
- DNAH9 | c.6545C>T p.P2182L | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs908902017, COSV52334621; called by muse, mutect2, varscan2
- DNAH9 | c.7169A>G p.Q2390R | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52334633; called by muse, mutect2
- DSC2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs368082152; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUSP7 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.655); catalogued as rs374371636, COSV99623677; called by muse, mutect2, varscan2
- DYRK4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV50537819; called by muse, mutect2
- ECM1 | c.1519G>T p.V507L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV60871810; called by muse, mutect2, varscan2
- ECPAS | c.707A>G p.Q236R | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV52191784; called by muse, mutect2, varscan2
- EEF2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1285177919, COSV58578622; called by muse, mutect2, varscan2
- EIF3B | c.2294A>G p.Q765R | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV62802677; called by muse, mutect2
- ELL | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53211149; called by muse, mutect2, varscan2
- ENO1 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as COSV52302717, COSV99319007; called by muse, mutect2, varscan2
- EPHB1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV67654238, COSV67675155; called by muse, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | catalogued as rs756407271; called by pindel, varscan2
- EPS15L1 | c.2179T>A p.L727I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV50167249, COSV50168201; called by muse, mutect2, varscan2
- ESPL1 | c.2558A>G p.Y853C | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV57757410; called by muse, mutect2, varscan2
- ESRP1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 57/425 reads (13%) | catalogued as COSV64407875; called by muse, mutect2, varscan2
- ETFDH | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56986958; called by muse, mutect2, varscan2
- F2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV61314763; called by muse, mutect2
- FAM214B | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59715022; called by muse, mutect2, varscan2
- FAM228A | c.418T>G p.Y140D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV54594716; called by muse, mutect2, varscan2
- FAM72A | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 78/1366 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs782256151, COSV57917879; called by muse, mutect2
- FAM78A | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771097879, COSV55991838; called by muse, mutect2, varscan2
- FAT3 | c.1911del p.K637Nfs*3 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs1311077918; called by mutect2, pindel
- FAT4 | c.3578A>G p.Q1193R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.974); catalogued as COSV67881544; called by muse, mutect2, varscan2
- FAT4 | c.14039A>G p.Y4680C | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs1259414671, COSV58672038; called by muse, mutect2, varscan2
- FDPS | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63113862; called by muse, mutect2, varscan2
- FERMT1 | c.1931A>G p.H644R | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54090678; called by muse, mutect2, varscan2
- FHOD3 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.155); catalogued as COSV57164652; called by muse, mutect2, varscan2
- FN1 | c.6910G>A p.V2304I (on ENST00000359671 / NM_001365524.2; = p.V2273I on NM_002026.4) | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs561274088, COSV60546772; called by muse, mutect2, varscan2
- FNDC1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV51931046; called by muse, mutect2, varscan2
- FNIP1 | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57194005; called by muse, mutect2
- FRAS1 | c.7774G>A p.E2592K | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs368306704, COSV53631671; called by muse, mutect2, varscan2
- FREM1 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 65/469 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV63087139; called by muse, mutect2, varscan2
- FUT3 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV54604541; called by muse, mutect2, varscan2
- GABRA5 | c.910A>C p.S304R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59475981; called by muse, mutect2, varscan2
- GABRG3 | c.1062G>T p.S354= | Splice Region (SNP) | VAF 22/312 reads (7%) | catalogued as COSV61510418; called by muse, mutect2
- GALR1 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV55315905; called by muse, mutect2
- GCN1 | c.6590T>C p.L2197P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56103992; called by muse, mutect2
- GDPD4 | c.418A>G p.R140G | Missense Mutation (SNP) | VAF 31/586 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV60017158; called by muse, mutect2
- GFOD1 | c.50T>C p.I17T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV64953045; called by muse, mutect2
- GJD2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV51747109; called by muse, mutect2, varscan2
- GOLM2 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 142/349 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as rs779703944, COSV55461548; called by muse, mutect2, varscan2
- GOT2 | c.629A>G p.H210R | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55330706; called by muse, mutect2, varscan2
- GP6 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs767901432, COSV59976378; called by mutect2, varscan2
- GPATCH1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.031); catalogued as rs367677391; called by muse, mutect2, varscan2
- GPR158 | c.2981C>T p.T994I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs977757831, COSV66265549; called by muse, mutect2, varscan2
- GRM6 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs753571357, COSV51434064; called by muse, mutect2, varscan2
- GRTP1 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV58148551; called by muse, mutect2, varscan2
- GSTM1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 264/669 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs781192005, COSV59166495; called by muse, mutect2, varscan2
- H2BC5 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56799864; called by muse, mutect2
- H3C3 | c.361A>C p.M121L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV63550669; called by muse, mutect2, varscan2
- HARS2 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56905547; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs748396956; called by mutect2, varscan2
- HDLBP | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60492126; called by muse, mutect2, varscan2
- HECTD4 | c.6724G>A p.A2242T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66386813; called by muse, mutect2, varscan2
- HEPH | c.2489C>T p.A830V (on ENST00000343002; = p.A563V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757226849, COSV57959104; called by muse, mutect2, varscan2
- HIBADH | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV55311585; called by muse, mutect2, varscan2
- HKDC1 | c.596T>C p.M199T | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1282133173, COSV63575527; called by muse, mutect2, varscan2
- HNRNPH1 | c.650G>T p.R217I | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV100270939, COSV61484861; called by muse, mutect2, varscan2
- HRG | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 111/458 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1229953228, COSV51644052; called by muse, varscan2
- HSD17B1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1366007750, COSV56797083; called by muse, mutect2, varscan2
- HSPB8 | c.266dup p.P90Tfs*37 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs773017653; called by mutect2, varscan2
- HTR2A | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66326657; called by muse, mutect2, varscan2
- HUWE1 | c.11338C>T p.R3780C | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV53335006; called by muse, mutect2
- HYDIN | c.9784G>A p.A3262T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763632956, COSV66858141; called by muse, mutect2, varscan2
- IGSF10 | c.6771del p.K2257Nfs*47 | Frame Shift Del (DEL) | VAF 45/185 reads (24%) | catalogued as rs754584576; called by mutect2, pindel, varscan2
- IL24 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.203); catalogued as rs755548073, COSV54320008; called by muse, mutect2, varscan2
- IL7R | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 94/507 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1057520828, COSV57405909; ClinVar: likely benign; called by muse, mutect2, varscan2
- ILK | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV54448857; called by muse, mutect2, varscan2
- INPPL1 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1394942069, COSV53353340; called by muse, mutect2
- INTS2 | c.1171C>A p.L391M | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52150929; called by muse, mutect2, varscan2
- IQCF2 | c.112-2A>G p.X38_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as COSV60761085; called by muse, mutect2, varscan2
- IQUB | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 143/429 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV61236987; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 23/194 reads (12%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 67/300 reads (22%) | catalogued as rs753256170; called by mutect2, pindel, varscan2
- KCNS2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV54637287; called by muse, mutect2, varscan2
- KDM1A | c.787A>G p.N263D | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63086639; called by muse, mutect2
- KDM5B | c.4035A>T p.E1345D | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52504137; called by muse, mutect2, varscan2
- KIAA0100 | c.2800C>A p.L934I | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66490652; called by muse, mutect2
- KIF18A | c.149_151del p.E50del | In Frame Del (DEL) | VAF 26/166 reads (16%) | catalogued as rs1230388813; called by pindel, varscan2
- KIF23 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs560577725, COSV52977431; called by muse, mutect2, varscan2
- KIRREL3 | c.1459A>G p.N487D | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV69383703; called by muse, mutect2, varscan2
- KIZ | c.1056del p.H352Qfs*31 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as COSV99852060; called by mutect2, pindel
- KLHL15 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60139175; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 25/131 reads (19%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KRT16 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs765215802, COSV56967021; called by muse, mutect2, varscan2
- LAMA2 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150586612, COSV70338895; called by muse, mutect2, varscan2
- LAMA2 | c.6521T>C p.V2174A | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70338900; called by muse, mutect2
- LAMP1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs756990012, COSV58148543; called by muse, mutect2, varscan2
- LARP1B | c.2257del p.M753Cfs*21 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | catalogued as rs1311334991; called by mutect2, pindel, varscan2
- LBR | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs202123513, COSV55287449; ClinVar: uncertain significance; called by muse, varscan2
- LMLN | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV57597545, COSV57597911; called by muse, mutect2, varscan2
- LONP2 | c.965G>A p.W322* | Nonsense Mutation (SNP) | VAF 71/209 reads (34%) | catalogued as COSV53520495; called by muse, mutect2, varscan2
- LPL | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 173/322 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs753984721, COSV60930040; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 81/375 reads (22%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRK2 | c.5207A>G p.Q1736R | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs1271888113, COSV54144340; called by muse, mutect2, varscan2
- MAGEC2 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.068); catalogued as rs749047320, COSV55997746; called by muse, mutect2, varscan2
- MAN2B2 | c.1829C>T p.T610M | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs184138382; called by muse, mutect2, varscan2
- MAN2C1 | c.3040C>A p.L1014I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV51226486; called by muse, mutect2, varscan2
- MAP3K13 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377513650; called by muse, mutect2, varscan2
- MAP3K15 | c.528A>G p.A176= | Splice Region (SNP) | VAF 22/163 reads (13%) | catalogued as COSV58826117; called by muse, mutect2, varscan2
- MAP3K6 | c.2446C>A p.P816T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58870243; called by muse, mutect2
- MAP6 | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 17/417 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV59074285; called by muse, mutect2
- MAT1A | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64744665; called by muse, mutect2
- MBP | c.883A>G p.S295G (on ENST00000355994 / NM_001025101.2; = p.S177G on NM_002385.3) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as rs148716184; called by muse, mutect2, varscan2
- MBP | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs535536627, COSV100592505, COSV63556473; called by muse, mutect2, varscan2
- MED12 | c.4225A>G p.S1409G | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV61332081; called by muse, mutect2
- METAP2 | c.1124A>G p.H375R | Missense Mutation (SNP) | VAF 90/598 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51562021; called by muse, mutect2, varscan2
- METTL4 | c.1345T>C p.W449R | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60602936; called by muse, mutect2, varscan2
- MFAP5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 133/350 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779463853, COSV63945085, COSV63945860; called by muse, mutect2, varscan2
- MGA | c.4058G>A p.S1353N | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV54949091, COSV54965337; called by muse, mutect2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 37/95 reads (39%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MME | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.75); catalogued as rs746423553, COSV64706032; called by muse, mutect2, varscan2
- MMP11 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as rs764598466, COSV53155410; called by muse, mutect2, varscan2
- MOGAT3 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV56172760; called by muse, mutect2, varscan2
- MROH8 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV54117332; called by muse, mutect2, varscan2
- MSH6 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52274587; called by muse, mutect2, varscan2
- MSRA | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs139278254; called by muse, mutect2
- MT1M | c.177C>G p.C59W | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51947158; called by muse, mutect2, varscan2
- MTOR | c.3065T>C p.F1022S | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV63868522; called by muse, mutect2, varscan2
- MYEF2 | c.1305T>C p.L435= | Splice Region (SNP) | VAF 54/337 reads (16%) | catalogued as COSV51045993; called by muse, mutect2, varscan2
- MYF6 | c.584G>T p.R195M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); catalogued as COSV57350773; called by muse, mutect2, varscan2
- MYH1 | c.867T>G p.F289L | Missense Mutation (SNP) | VAF 59/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56843817; called by muse, mutect2, varscan2
- MYH2 | c.5183G>A p.S1728N | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV55431792; called by muse, mutect2
- MYH4 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs144778193, COSV55111888, COSV55125528; called by muse, mutect2, varscan2
- MYLK | c.4984A>G p.M1662V | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1559985971, COSV60605007; called by muse, mutect2, varscan2
- MYO6 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1166992066, COSV64117408; called by muse, mutect2, varscan2
- MYO6 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 66/608 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1165964527, COSV64117413; called by muse, varscan2
- NAALADL2 | c.1554del p.N520Mfs*12 | Frame Shift Del (DEL) | VAF 38/143 reads (27%) | catalogued as rs1478908176, COSV69154859; called by mutect2, pindel, varscan2
- NBEA | c.7419del p.K2473Nfs*13 | Frame Shift Del (DEL) | VAF 85/414 reads (21%) | catalogued as rs754479937; called by mutect2, pindel, varscan2
- NBEAL2 | c.4361C>T p.T1454M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs371607035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBPF11 | c.1089C>T p.L363= | Splice Region (SNP) | VAF 56/190 reads (29%) | catalogued as rs78261742; called by muse, mutect2, varscan2
- NDRG3 | c.88T>G p.C30G | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV62421042; called by muse, mutect2, varscan2
- NDST2 | c.2327A>G p.D776G | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55212823; called by muse, mutect2
- NEDD4L | c.768C>A p.S256R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56840527; called by mutect2, varscan2
- NEFH | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60215124; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs759081520; called by mutect2, pindel
- NEUROD1 | c.1036A>G p.M346V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV54548192; called by muse, mutect2
- NIBAN1 | c.1555-2A>G p.X519_splice | Splice Site (SNP) | VAF 41/391 reads (10%) | catalogued as rs779954800, COSV62283052; called by muse, mutect2, varscan2
- NIPBL | c.7350G>A p.M2450I | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.262); catalogued as COSV56942566; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NKD1 | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV51689460, COSV51695185; called by muse, mutect2, varscan2
- NLRP13 | c.2722A>G p.R908G | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756355943, COSV61619977; called by muse, mutect2
- NME1 | c.457T>C p.*153Rext*91 | Nonstop Mutation (SNP) | VAF 92/393 reads (23%) | catalogued as COSV50146932; called by muse, mutect2, varscan2
- NR2C2 | c.1571A>G p.E524G (on ENST00000393102; = p.E543G on NM_003298.5) | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV60144683; called by muse, varscan2
- NRSN2 | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV66526563; called by muse, mutect2, varscan2
- NSD3 | c.2360T>C p.F787S | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV57666993; called by muse, mutect2, varscan2
- OAS3 | c.1610T>C p.L537P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57444145; called by muse, mutect2, varscan2
- ODR4 | c.999del p.D334Ifs*22 | Frame Shift Del (DEL) | VAF 54/450 reads (12%) | catalogued as rs776869231; called by mutect2, varscan2
- OGDH | c.240del p.R81Afs*19 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs777887578; called by mutect2, varscan2
- OLFML3 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs766941607, COSV57434667; called by muse, mutect2, varscan2
- OR1I1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV52917333; called by muse, mutect2, varscan2
- OR4A16 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs770011577, COSV59041871, COSV59043405; called by muse, mutect2, varscan2
- OR4E2 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 215/600 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV57731398; called by muse, mutect2, varscan2
- OR6K2 | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 102/383 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV62743105, COSV62744393; called by muse, mutect2, varscan2
- OR7G2 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59687312; called by muse, mutect2
- OR9A2 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV63306302; called by muse, mutect2, varscan2
- OSBPL3 | c.1496-2A>G p.X499_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | catalogued as COSV57652796; called by muse, mutect2
- OTOP1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as rs200213513, COSV56390815; called by muse, mutect2, varscan2
- P2RX3 | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV54441481; called by muse, mutect2, varscan2
- PACRG | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs199844557, COSV61296838; called by muse, mutect2, varscan2
- PAPPA2 | c.5251T>C p.C1751R | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62790885, COSV62798922; called by muse, mutect2
- PARP3 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV67168114; called by muse, mutect2, varscan2
- PARP4 | c.4114A>G p.T1372A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV67960565; called by muse, mutect2, varscan2
- PATJ | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); catalogued as rs545651035, COSV57155825; called by muse, mutect2, varscan2
- PCDH10 | c.360dup p.S121Lfs*13 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | catalogued as rs759095467; called by mutect2, varscan2
- PCDHA12 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782742455, COSV56478487; called by muse, mutect2, varscan2
- PCDHB12 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53393221; called by muse, mutect2
- PDE3A | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.134); catalogued as COSV62968201; called by muse, mutect2, varscan2
- PEAR1 | c.1727G>A p.C576Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756746250, COSV52770834; called by muse, mutect2, varscan2
- PER1 | c.3794A>C p.D1265A | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57917363; called by muse, mutect2
- PFKP | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs757633268, COSV101126931, COSV66894933; called by muse, mutect2, varscan2
- PGLYRP1 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50516442; called by muse, mutect2, varscan2
- PHLDB2 | c.3481A>G p.K1161E (on ENST00000393925 / NM_001134439.2; = p.K1118E on NM_145753.2) | Missense Mutation (SNP) | VAF 73/450 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67308079; called by muse, mutect2, varscan2
- PIGR | c.1909T>C p.S637P | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV62903248; called by muse, mutect2, varscan2
- PIKFYVE | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 240/669 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1414178358, COSV52237080; called by mutect2, varscan2
- PKD1L1 | c.2998C>T p.P1000S | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV56958130; called by muse, varscan2
- PLAA | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1425927279, COSV68304524; called by muse, mutect2, varscan2
- PLD3 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as rs1313886181, CM140823, COSV62924179; called by muse, mutect2, varscan2
- POLL | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV54573590; called by muse, mutect2, varscan2
- POLR1B | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV54494849; called by muse, mutect2, varscan2
- POTEF | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.77); catalogued as rs767286650, COSV62539769; called by muse, mutect2, varscan2
- PPA2 | c.187T>C p.F63L | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as COSV58993415; called by muse, mutect2
- PPFIA1 | c.3349C>A p.L1117I | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54131622; called by muse, mutect2
- PPP3CB | c.1429T>C p.C477R | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55018600; called by muse, mutect2
- PPT1 | c.305C>A p.P102H (on ENST00000433473; = p.P103H on NM_000310.4) | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV65655394; called by muse, mutect2, varscan2
- PRAG1 | c.3746A>G p.Y1249C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100422766, COSV58157404; called by muse, mutect2, varscan2
- PRAG1 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs761501061, COSV58157421; called by muse, varscan2
- PREX2 | c.2369A>G p.E790G | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55751306; called by muse, mutect2
- PRKDC | c.11671A>T p.S3891C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV58043239; called by muse, mutect2, varscan2
- PRSS35 | c.872T>C p.M291T | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63800113; called by muse, mutect2
- PRUNE2 | c.6718C>T p.Q2240* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV65038013, COSV65046850; called by muse, mutect2, varscan2
- PTCHD1 | c.2473A>G p.R825G | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65059058; called by muse, mutect2, varscan2
- PTCHD4 | c.1684A>G p.N562D | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV59777938; called by muse, mutect2, varscan2
- PTPRA | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 111/552 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53778436; called by muse, mutect2, varscan2
- PTPRD | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV61929096; called by muse, mutect2, varscan2
- PTPRS | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1302269430, COSV53610398; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PTPRT | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs372713520, COSV61961422, COSV61995720; called by muse, mutect2, varscan2
- PUM2 | c.2274G>T p.M758I | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV57577921; called by muse, mutect2, varscan2
- R3HDM2 | c.2030A>G p.Y677C | Missense Mutation (SNP) | VAF 18/682 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61284909; called by muse, mutect2
- RAB11FIP5 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50247916; called by muse, mutect2
- RAB22A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as rs148684735; called by muse, mutect2, varscan2
- RAB6B | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs749807184, COSV53312118; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 75/196 reads (38%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAD9B | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 16/275 reads (6%) | catalogued as COSV62194356; called by muse, mutect2
- RAPGEF3 | c.2530A>G p.M844V (on ENST00000389212; = p.M802V on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs759034284, COSV50198198; called by muse, mutect2
- RBBP8 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59090700; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 175/779 reads (22%) | catalogued as COSV56484832; called by mutect2, varscan2
- RFLNB | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs935784493, COSV61239084; called by muse, mutect2
- RGN | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as rs376108151, COSV60275614; called by muse, mutect2, varscan2
- RHCG | c.1370_1378del p.G457_S459del | In Frame Del (DEL) | VAF 82/249 reads (33%) | catalogued as rs1420440829; called by mutect2, varscan2
- RIC1 | c.3752A>C p.E1251A | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV52605099, COSV52615780; called by muse, mutect2, varscan2
- RIPK4 | c.1705del p.R569Gfs*43 (on ENST00000352483; = p.R521Gfs*43 on NM_020639.3) | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as COSV60185694; called by mutect2, pindel, varscan2
- RNF10 | c.1399T>C p.C467R | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV58043546; called by muse, mutect2, varscan2
- RNF123 | c.1813C>A p.L605M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59684350; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 44/193 reads (23%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs761571713, COSV60415198; called by muse, mutect2
- RNPEP | c.1102A>G p.T368A | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV55238807; called by muse, mutect2
- RNPEP | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55238818, COSV99821815; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 86/202 reads (43%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KC1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 29/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65297201; called by muse, mutect2
- RPTOR | c.348+2T>C p.X116_splice | Splice Site (SNP) | VAF 22/182 reads (12%) | catalogued as COSV60803436; called by muse, mutect2, varscan2
- RTF2 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50127802; called by muse, mutect2, varscan2
- RTTN | c.6584T>C p.L2195S | Missense Mutation (SNP) | VAF 187/520 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV55341482; called by muse, mutect2, varscan2
- RUBCN | c.2384T>C p.I795T | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV56362572; called by muse, mutect2, varscan2
- RYR1 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs1202647394, COSV62089209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.3902T>A p.F1301Y | Missense Mutation (SNP) | VAF 218/414 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.246); catalogued as COSV63663038; called by muse, mutect2, varscan2
- RYR3 | c.12082C>A p.L4028I (on ENST00000389232; = p.L4029I on NM_001036.6) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761950338, COSV66778317; called by muse, mutect2, varscan2
- S100A13 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59884365; called by muse, mutect2
- SACS | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66534532; called by muse, mutect2, varscan2
- SATB2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV53478415; called by muse, mutect2, varscan2
- SBNO1 | c.818A>G p.D273G (on ENST00000420886; = p.D272G on NM_018183.5) | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs1482371713, COSV57338990; called by muse, mutect2
- SCN3A | c.3835A>G p.I1279V | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV51801657; called by muse, mutect2
- SEL1L | c.2191A>T p.T731S | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60919129; called by muse, mutect2
- SEMA4F | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); catalogued as rs778118707, COSV60281939; called by muse, mutect2, varscan2
- SERPINB2 | c.1120G>T p.G374* | Nonsense Mutation (SNP) | VAF 24/180 reads (13%) | catalogued as COSV53071889; called by muse, mutect2
- SETBP1 | c.4016A>G p.H1339R | Missense Mutation (SNP) | VAF 72/440 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1238612391, COSV56313386; called by muse, mutect2, varscan2
- SETDB1 | c.2549G>A p.G850D | Missense Mutation (SNP) | VAF 193/334 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54977566; called by muse, mutect2, varscan2
- SFMBT2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs750758773, COSV62805471; called by muse, mutect2, varscan2
- SH3GLB1 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 74/832 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV65279115; called by muse, mutect2
- SHQ1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV57763984; called by muse, mutect2
- SI | c.4769T>C p.L1590S | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52266392; called by muse, mutect2
- SIPA1L1 | c.3265A>G p.M1089V | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs749350454, COSV62168424; called by muse, mutect2, varscan2
- SIPA1L2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV53383701; called by muse, mutect2, varscan2
- SLC12A1 | c.3104G>A p.R1035H | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1358953771, COSV66791874; called by muse, mutect2, varscan2
- SLC27A5 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as COSV54018025, COSV54021561; called by muse, mutect2
- SLC3A2 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV58602839; called by muse, mutect2, varscan2
- SLC8A2 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.78); PolyPhen probably damaging (1); catalogued as COSV52637743; called by muse, mutect2, varscan2
- SLC9A6 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65787323; called by muse, mutect2
- SLCO2A1 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 135/481 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV60483640; called by muse, mutect2, varscan2
- SLF2 | c.2521A>G p.S841G | Missense Mutation (SNP) | VAF 219/576 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV53270859; called by muse, mutect2, varscan2
- SLU7 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs565652679, COSV51786533, COSV99775443; called by muse, mutect2, varscan2
- SLX4IP | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV57944163; called by muse, mutect2, varscan2
- SNRPG | c.14A>G p.H5R | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV50682381; called by muse, mutect2
- SORBS3 | c.1013T>C p.L338P | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV53551827; called by muse, mutect2, varscan2
- SORCS3 | c.3313G>T p.V1105L | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63802985; called by muse, mutect2
- SPEN | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1459952195, COSV65357850; called by muse, mutect2
- SPINDOC | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1022972421, COSV53691919; called by muse, mutect2, varscan2
- SPRTN | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV50477539; called by muse, mutect2, varscan2
- SPRY4 | c.593C>T p.T198M (on ENST00000434127 / NM_001127496.3; = p.T221M on NM_030964.4) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs372822397; called by muse, mutect2, varscan2
- SPZ1 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV57062323; called by muse, mutect2, varscan2
- SUGCT | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1213847486, COSV59314536; called by muse, mutect2, varscan2
- SULT1A2 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 25/463 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV57680847; called by muse, mutect2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 48/322 reads (15%) | catalogued as rs570102997; called by mutect2, varscan2
- SYCP3 | c.643dup p.I215Nfs*27 | Frame Shift Ins (INS) | VAF 75/222 reads (34%) | catalogued as rs761136347; called by mutect2, varscan2
- SYNE1 | c.9279A>G p.I3093M (on ENST00000367255 / NM_182961.4; = p.I3100M on NM_033071.3) | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV54909892; called by muse, mutect2, varscan2
- TAB2 | c.271G>T p.G91* | Nonsense Mutation (SNP) | VAF 16/402 reads (4%) | catalogued as COSV53851082; called by muse, mutect2
- TAS2R38 | c.940T>C p.W314R | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs1554444324, COSV71884983; called by muse, mutect2
- TASOR2 | c.4567A>G p.R1523G | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60165541; called by muse, mutect2, varscan2
- TAT | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV63532320; called by muse, mutect2, varscan2
- TBC1D12 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV56552395; called by muse, mutect2, varscan2
- TBC1D14 | c.1618A>G p.M540V | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs1336050553, COSV68984532; called by muse, mutect2, varscan2
- TBC1D22A | c.1312C>A p.L438M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61435700; called by muse, mutect2
- TCN2 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53190700; called by muse, mutect2, varscan2
- TEK | c.3112C>T p.P1038S | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66227507; called by muse, mutect2, varscan2
- TENM2 | c.7936G>A p.G2646R (on ENST00000518659 / NM_001122679.2; = p.G2407R on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1314352171, COSV69122810; called by muse, mutect2, varscan2
- THEG | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as COSV61073083; called by muse, mutect2
- THSD7B | c.3503C>T p.A1168V (on ENST00000272643; = p.A1166V on NM_001316349.2) | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV55655517; called by muse, mutect2
- THUMPD2 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 12/412 reads (3%) | catalogued as rs1194232053, COSV53186528; called by muse, mutect2
- TIGIT | c.175T>C p.W59R | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67328554; called by muse, mutect2
- TMC6 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56940512; called by muse, mutect2, varscan2
- TMCO4 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV53869242; called by muse, mutect2, varscan2
- TMEM135 | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV59696522; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 56/202 reads (28%) | catalogued as rs781830688; called by mutect2, varscan2
- TMPRSS11B | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV60291275; called by muse, mutect2, varscan2
- TMPRSS9 | c.1066C>A p.P356T (on ENST00000648592; = p.P322T on NM_182973.2) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV60225671; called by mutect2, varscan2
- TNKS | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV60051931; called by muse, mutect2
- TNS3 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60786919; called by muse, mutect2
- TOPORS | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 125/319 reads (39%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.886); catalogued as rs918865207, COSV62116143; called by muse, mutect2, varscan2
- TP53BP2 | c.2176G>A p.A726T (on ENST00000343537 / NM_001031685.3; = p.A597T on NM_005426.2) | Missense Mutation (SNP) | VAF 85/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59066408; called by muse, mutect2, varscan2
- TPCN1 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV59232420; called by muse, mutect2, varscan2
- TRAF1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.084); catalogued as rs200946021, COSV65867737; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1439A>G p.K480R | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV50550548; called by muse, mutect2, varscan2
- TRAF6 | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.562); catalogued as COSV61921951; called by muse, varscan2
- TRANK1 | c.7454T>G p.L2485R | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57140792; called by muse, mutect2
- TRBV28 | c.154T>C p.F52L | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs762963718; called by muse, mutect2, varscan2
- TRIOBP | c.5603C>T p.S1868L (on ENST00000644935 / NM_001039141.3; = p.S155L on NM_007032.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58525696; called by muse, mutect2, varscan2
- TRPM1 | c.3014T>C p.M1005T | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV56630684; called by muse, mutect2
- TRPM1 | c.1348C>G p.R450G | Missense Mutation (SNP) | VAF 608/1698 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV56630696, COSV99856888; called by mutect2, varscan2
- TSPAN16 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as COSV57441455; called by muse, mutect2, varscan2
- TSPYL5 | c.662G>T p.R221M | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59070991; called by muse, mutect2, varscan2
- TTC30A | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63100469; called by muse, mutect2
- TTC39A | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.158); catalogued as COSV52956743; called by muse, mutect2, varscan2
- TTF1 | c.821del p.K274Sfs*149 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs770528448; called by mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.62909A>G p.Y20970C (on ENST00000591111; = p.Y13546C on NM_003319.4) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | PolyPhen benign (0.386); catalogued as COSV59893688; called by muse, mutect2, varscan2
- TUBB4A | c.58-2A>G p.X20_splice | Splice Site (SNP) | VAF 14/146 reads (10%) | catalogued as COSV51152269; called by muse, mutect2, varscan2
- TUBB6 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV52312807; called by muse, mutect2, varscan2
- TWNK | c.1462T>C p.F488L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV52966463; called by muse, mutect2, varscan2
- TXNRD2 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57632018; called by muse, mutect2, varscan2
- UBN2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56027768; called by muse, mutect2, varscan2
- UNC5CL | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs774664002, COSV55108997; called by muse, mutect2, varscan2
- UPB1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV58112077; called by muse, mutect2, varscan2
- USP21 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV57086781; called by muse, mutect2, varscan2
- USP45 | c.2072A>G p.Q691R | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59678351; called by muse, mutect2
- UVRAG | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370544443; called by muse, mutect2, varscan2
- VCAM1 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54117805; called by muse, mutect2
- VPS45 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 23/193 reads (12%) | catalogued as rs782545355, COSV64886979; called by muse, mutect2, varscan2
- VPS50 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs371874797, COSV52492650; called by muse, mutect2, varscan2
- WASHC2A | c.4004T>C p.L1335P | Missense Mutation (SNP) | VAF 286/811 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50953139; called by muse, mutect2, varscan2
- WASHC5 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59194130; called by muse, mutect2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR70 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV54266781; called by muse, mutect2
- WNT9A | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.123); catalogued as COSV55293346; called by muse, mutect2, varscan2
- WSCD1 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV58493667; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 20/187 reads (11%) | catalogued as rs762052135; called by mutect2, varscan2
- YARS1 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1489182397, COSV53862408; called by muse, mutect2
- ZBTB16 | c.1793-2A>G p.X598_splice | Splice Site (SNP) | VAF 17/118 reads (14%) | catalogued as COSV60089316; called by muse, mutect2, varscan2
- ZCCHC12 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 13/374 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV59570935; called by muse, mutect2
- ZMYM3 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV58736138; called by muse, mutect2
- ZNF202 | c.951A>G p.T317= | Splice Region (SNP) | VAF 36/265 reads (14%) | catalogued as COSV60246417; called by muse, mutect2, varscan2
- ZNF207 | c.1364C>A p.P455H | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV58298869; called by muse, mutect2, varscan2
- ZNF285 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV58407992; called by muse, mutect2
- ZNF410 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1461370998, COSV57909860; called by muse, mutect2
- ZNF462 | c.1597A>T p.M533L | Missense Mutation (SNP) | VAF 93/278 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1329551150, COSV52930598; called by muse, mutect2, varscan2
- ZNF526 | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.809); catalogued as COSV56628822; called by muse, mutect2
- ZNF680 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as COSV59013978; called by muse, mutect2
- ZNF98 | c.305del p.N102Ifs*6 | Frame Shift Del (DEL) | VAF 74/224 reads (33%) | catalogued as rs757764317, COSV63337477; called by mutect2, varscan2
- ZSCAN5B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs200185124, COSV61999211; called by muse, mutect2, varscan2
- ZZEF1 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as rs780829945, COSV67555995; called by muse, mutect2, varscan2
- ABR | c.205del p.D69Mfs*23 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- ADGRG6 | c.257_258del p.F86* | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.4828del p.Y1610Tfs*36 | Frame Shift Del (DEL) | VAF 56/474 reads (12%) | called by mutect2, pindel, varscan2
- AMPD2 | c.737del p.P246Lfs*63 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- ARFGEF2 | c.1414del p.M472Cfs*3 | Frame Shift Del (DEL) | VAF 60/183 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.2272del p.Q758Rfs*75 | Frame Shift Del (DEL) | VAF 51/164 reads (31%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by mutect2, varscan2
- BBX | c.2088del p.K696Nfs*270 (on ENST00000325805 / NM_001142568.3; = p.K696Nfs*240 on NM_020235.7) | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | called by mutect2, varscan2
- C6orf58 | c.756dup p.P253Sfs*6 | Frame Shift Ins (INS) | VAF 59/314 reads (19%) | called by mutect2, pindel, varscan2
- CCL1 | c.259dup p.M87Nfs*44 | Frame Shift Ins (INS) | VAF 43/313 reads (14%) | called by mutect2, pindel, varscan2
- CCT6B | c.237del p.V80* | Frame Shift Del (DEL) | VAF 34/282 reads (12%) | called by mutect2, pindel, varscan2
- CD1E | c.993del p.K331Nfs*47 | Frame Shift Del (DEL) | VAF 66/505 reads (13%) | called by pindel, varscan2
- CENPH | c.344del p.N115Tfs*16 | Frame Shift Del (DEL) | VAF 36/112 reads (32%) | called by mutect2, varscan2
- COX19 | c.270del p.K90Nfs*4 | Frame Shift Del (DEL) | VAF 28/194 reads (14%) | called by mutect2, pindel, varscan2
- DDX60L | c.1640dup p.E548Gfs*9 | Frame Shift Ins (INS) | VAF 24/207 reads (12%) | called by mutect2, pindel, varscan2
- DNM2 | c.1351del p.R451Gfs*28 | Frame Shift Del (DEL) | VAF 21/148 reads (14%) | called by mutect2, pindel, varscan2
- DPP4 | c.1092del p.F364Lfs*26 | Frame Shift Del (DEL) | VAF 39/279 reads (14%) | called by pindel, varscan2
- EPN1 | c.1398del p.T467Pfs*22 (on ENST00000270460 / NM_001321263.1; = p.T441Pfs*22 on NM_013333.3) | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | called by mutect2, varscan2
- ERBIN | c.198del p.F66Lfs*9 | Frame Shift Del (DEL) | VAF 155/522 reads (30%) | called by mutect2, pindel, varscan2
- FAM171B | c.2081del p.K694Rfs*18 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel, varscan2
- FREM2 | c.1141dup p.S381Ffs*20 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 33/98 reads (34%) | called by mutect2, varscan2
- ICAM1 | c.200dup p.E68Gfs*13 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- IFT52 | c.510del p.F170Lfs*5 | Frame Shift Del (DEL) | VAF 47/246 reads (19%) | called by mutect2, pindel, varscan2
- IRF8 | c.1253del p.F418Sfs*35 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- KMT2C | c.3291_3293del p.E1097del | In Frame Del (DEL) | VAF 38/164 reads (23%) | called by pindel, varscan2
- KMT2D | c.7548del p.N2517Ifs*26 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- LITAF | c.263del p.L88Wfs*15 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | called by mutect2, pindel, varscan2
- MAP2 | c.4386del p.A1463Qfs*25 | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | called by mutect2, pindel, varscan2
- MASTL | c.1372del p.I458Lfs*9 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- MMP12 | c.318dup p.P107Afs*14 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- MTREX | c.2376del p.V793Sfs*5 | Frame Shift Del (DEL) | VAF 18/192 reads (9%) | called by mutect2, pindel
- MYCT1 | c.85_86del p.F29Rfs*22 | Frame Shift Del (DEL) | VAF 27/165 reads (16%) | called by mutect2, pindel, varscan2
- MYO19 | c.1268A>G p.D423G | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NF1 | c.1882del p.Y628Tfs*3 | Frame Shift Del (DEL) | VAF 109/523 reads (21%) | called by mutect2, pindel, varscan2
- NHLRC3 | c.462del p.G155Afs*4 | Frame Shift Del (DEL) | VAF 31/312 reads (10%) | called by mutect2, pindel, varscan2
- NLRP14 | c.1595del p.L532Cfs*5 | Frame Shift Del (DEL) | VAF 58/183 reads (32%) | called by pindel, varscan2
- OR2A42 | c.171del p.M58Cfs*40 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, varscan2
- PACS1 | c.1574G>T p.R525M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PIK3C2B | c.393del p.F131Lfs*17 | Frame Shift Del (DEL) | VAF 83/647 reads (13%) | called by mutect2, pindel, varscan2
- PLAGL2 | c.30del p.W11Gfs*15 | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- POLA1 | c.3158del p.K1053Rfs*25 | Frame Shift Del (DEL) | VAF 43/234 reads (18%) | called by mutect2, varscan2
- PPIL4 | c.100dup p.I34Nfs*40 | Frame Shift Ins (INS) | VAF 79/265 reads (30%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.2815del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- PSD2 | c.828del p.S277Afs*2 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- PTPN5 | c.165_166dup p.M56Rfs*70 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | called by mutect2, varscan2
- RAG1 | c.619del p.H207Tfs*57 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- RAPH1 | c.3227del p.P1076Lfs*41 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- REXO5 | c.1307del p.L436* | Frame Shift Del (DEL) | VAF 59/396 reads (15%) | called by mutect2, pindel, varscan2
- RNF146 | c.1013del p.G338Vfs*4 (on ENST00000368314 / NM_001242850.2; = p.G337Vfs*4 on NM_030963.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- RP1L1 | c.4084A>T p.T1362S | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINI1 | c.248del p.N83Mfs*8 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, pindel, varscan2
- SIX4 | c.34dup p.S12Kfs*278 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- SLC30A5 | c.2044del p.W682Gfs*16 | Frame Shift Del (DEL) | VAF 34/292 reads (12%) | called by mutect2, pindel, varscan2
- SLC4A1AP | c.1134del p.F378Lfs*8 | Frame Shift Del (DEL) | VAF 47/227 reads (21%) | called by mutect2, pindel, varscan2
- TECTA | c.5505_5508del p.R1835Sfs*77 | Frame Shift Del (DEL) | VAF 68/232 reads (29%) | called by pindel, varscan2
- TGFBRAP1 | c.1755del p.K585Nfs*7 | Frame Shift Del (DEL) | VAF 244/582 reads (42%) | called by mutect2, varscan2
- THAP5 | c.825del p.F275Lfs*37 (on ENST00000415914 / NM_001130475.3; = p.F233Lfs*37 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/175 reads (34%) | called by mutect2, pindel, varscan2
- TRAV34 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 63/317 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TRMT10B | c.474del p.A159Lfs*23 | Frame Shift Del (DEL) | VAF 57/533 reads (11%) | called by mutect2, pindel, varscan2
- UGT2B10 | c.1099del p.T367Pfs*5 | Frame Shift Del (DEL) | VAF 23/152 reads (15%) | called by mutect2, varscan2
- VN1R5 | c.408del p.C137Afs*? | Frame Shift Del (DEL) | VAF 93/363 reads (26%) | called by mutect2, pindel, varscan2
- VPS13B | c.5608del p.T1870Qfs*6 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | called by mutect2, pindel, varscan2
- ZDHHC14 | c.631del p.Y211Ifs*10 | Frame Shift Del (DEL) | VAF 136/446 reads (30%) | called by mutect2, pindel, varscan2
- ZNF644 | c.2307_2313del p.L769Ffs*36 | Frame Shift Del (DEL) | VAF 46/133 reads (35%) | called by mutect2, pindel, varscan2
- ZNF75A | c.759del p.K253Nfs*122 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel, varscan2
- A2M | c.3357T>C p.P1119= | Silent (SNP) | VAF 55/156 reads (35%) | catalogued as COSV59383034; called by muse, mutect2, varscan2
- ADD1 | c.453G>A p.A151= | Silent (SNP) | VAF 107/1143 reads (9%) | catalogued as rs745364833, COSV53266471; called by muse, mutect2
- ADGRF2 | c.606G>A p.Q202= (on ENST00000296862 / NM_001368115.2; = p.Q134= on NM_153839.7) | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as rs1005180900, COSV57286501; called by muse, mutect2, varscan2
- AGTR1 | c.567A>G p.S189= | Silent (SNP) | VAF 67/250 reads (27%) | catalogued as COSV62557329; called by muse, mutect2, varscan2
- AMER2 | c.1998C>T p.D666= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV63436164; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.921T>C p.T307= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV51840709; called by muse, mutect2
- ARG1 | c.603T>C p.T201= | Silent (SNP) | VAF 60/338 reads (18%) | catalogued as rs767964970, CD165234, COSV51580588; called by muse, mutect2, varscan2
- ARHGAP29 | c.1830T>C p.A610= | Silent (SNP) | VAF 83/540 reads (15%) | catalogued as COSV53108291; called by muse, mutect2, varscan2
- ARHGEF26 | c.1953C>A p.S651= | Silent (SNP) | VAF 72/1222 reads (6%) | catalogued as COSV62843918; called by muse, mutect2
- ARHGEF28 | c.3474T>G p.A1158= | Silent (SNP) | VAF 97/296 reads (33%) | catalogued as COSV55247661; called by muse, mutect2, varscan2
- ARID1A | c.3399C>A p.P1133= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV61372148, COSV61392458; called by muse, mutect2, varscan2
- ATP13A5 | c.2631T>C p.P877= | Silent (SNP) | VAF 322/1195 reads (27%) | catalogued as COSV60865832, COSV60876598; called by muse, mutect2, varscan2
- AURKB | c.939G>A p.S313= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as rs754393355, COSV60243532; called by muse, mutect2, varscan2
- BLM | c.723C>T p.G241= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV61921797; called by muse, mutect2
- BRWD3 | c.2595A>T p.G865= | Silent (SNP) | VAF 24/293 reads (8%) | catalogued as COSV64744019; called by muse, mutect2
- BSN | c.11682C>T p.S3894= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs903078174, COSV56513147; called by muse, mutect2
- CACNA1D | c.993G>A p.T331= | Silent (SNP) | VAF 97/377 reads (26%) | catalogued as rs772393855, COSV55437828; called by muse, mutect2, varscan2
- CACNA2D3 | c.1029T>C p.N343= | Silent (SNP) | VAF 130/929 reads (14%) | catalogued as COSV55514909; called by muse, mutect2, varscan2
- CCDC180 | c.4074A>G p.P1358= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV63826952; called by muse, mutect2, varscan2
- CCKBR | c.879C>T p.C293= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as COSV58098795; called by muse, mutect2, varscan2
- CELSR2 | c.5871T>C p.C1957= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV54766921; called by muse, mutect2
- CHI3L1 | c.927T>C p.H309= | Silent (SNP) | VAF 65/269 reads (24%) | catalogued as COSV55137136; called by muse, mutect2, varscan2
- CHIA | c.633C>A p.T211= (on ENST00000343320; = p.T103= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as COSV58473693; called by muse, mutect2
- CHST8 | c.717C>T p.F239= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52856339; called by muse, varscan2
- CLEC2D | c.9C>T p.D3= | Silent (SNP) | VAF 7/195 reads (4%) | catalogued as COSV51992578; called by muse, mutect2
- CNKSR2 | c.1149A>G p.P383= | Silent (SNP) | VAF 35/181 reads (19%) | catalogued as COSV54249683; called by muse, mutect2, varscan2
- CPA5 | c.1062G>A p.V354= | Silent (SNP) | VAF 4/98 reads (4%) | catalogued as COSV62568793; called by muse, mutect2
- CTCFL | c.855C>T p.H285= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV54770865; called by muse, mutect2, varscan2
- CX3CL1 | c.1014C>T p.T338= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV50055454; called by muse, mutect2, varscan2
- DAPK1 | c.1401C>T p.F467= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs777004845, COSV63784298; called by muse, mutect2, varscan2
- DCLRE1C | c.1848T>C p.P616= (on ENST00000378278 / NM_001350965.2; = p.P501= on NM_022487.4) | Silent (SNP) | VAF 79/582 reads (14%) | catalogued as rs1338665936, COSV57952518; called by muse, mutect2, varscan2
- DCUN1D3 | c.66T>C p.R22= | Silent (SNP) | VAF 45/282 reads (16%) | catalogued as COSV60952447; called by muse, mutect2, varscan2
- DEDD | c.219C>T p.R73= | Silent (SNP) | VAF 57/391 reads (15%) | catalogued as rs777379767, COSV63501180; called by muse, mutect2, varscan2
- DNAH2 | c.9564C>T p.R3188= | Silent (SNP) | VAF 54/185 reads (29%) | catalogued as rs765797518, COSV66716460; called by muse, mutect2, varscan2
- DNAH5 | c.9138T>C p.D3046= | Silent (SNP) | VAF 23/469 reads (5%) | catalogued as COSV54204644, COSV54222395; called by muse, mutect2
- DNAJC13 | c.3732T>C p.Y1244= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV53445874; called by muse, mutect2, varscan2
- DNAJC5 | c.429C>T p.G143= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs753956759, COSV62670871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNTTIP2 | c.1047A>G p.S349= | Silent (SNP) | VAF 60/317 reads (19%) | catalogued as rs912253015, COSV63283578; called by muse, mutect2, varscan2
- DSPP | c.1413T>C p.S471= | Silent (SNP) | VAF 61/276 reads (22%) | catalogued as COSV56807937; called by muse, mutect2, varscan2
- DVL3 | c.1899C>T p.S633= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53047041; called by mutect2, varscan2
- DYRK4 | c.1056G>A p.G352= | Silent (SNP) | VAF 26/363 reads (7%) | catalogued as rs1565543994, COSV50537826; called by muse, mutect2
- EIF4A3 | c.978C>T p.G326= | Silent (SNP) | VAF 140/517 reads (27%) | catalogued as rs779051281, COSV53919623; called by muse, varscan2
- EIF4G3 | c.1311T>C p.T437= | Silent (SNP) | VAF 38/325 reads (12%) | catalogued as COSV51674198; called by muse, mutect2, varscan2
- ELF4 | c.444T>C p.G148= | Silent (SNP) | VAF 28/529 reads (5%) | catalogued as COSV57451445; called by muse, mutect2
- ENAM | c.2532A>G p.E844= | Silent (SNP) | VAF 18/518 reads (3%) | catalogued as rs1184292372, COSV68535231; called by muse, mutect2
- EPHX1 | c.465C>T p.Y155= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as rs199979074, COSV55298760; called by muse, varscan2
- FAM126B | c.162G>A p.E54= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV53771501; called by muse, mutect2
- FAM167B | c.126A>G p.S42= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV61107304; called by muse, mutect2, varscan2
- FANCI | c.3343T>C p.L1115= (on ENST00000310775 / NM_001376911.1; = p.L1055= on NM_018193.3) | Silent (SNP) | VAF 35/176 reads (20%) | catalogued as COSV55522978; called by muse, mutect2, varscan2
- FLG | c.6108C>T p.H2036= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as COSV64236659; called by muse, mutect2, varscan2
- GAS2L1 | c.405C>T p.S135= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53329937; called by muse, mutect2, varscan2
- GLRA3 | c.165A>G p.S55= | Silent (SNP) | VAF 94/239 reads (39%) | catalogued as COSV56857853; called by muse, mutect2, varscan2
- GOLGA4 | c.1380T>C p.S460= | Silent (SNP) | VAF 156/655 reads (24%) | catalogued as COSV62709267; called by muse, mutect2, varscan2
- GPR179 | c.3027C>A p.P1009= (on ENST00000621958; = p.P1008= on NM_001004334.4) | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- GPR87 | c.618A>T p.A206= | Silent (SNP) | VAF 70/512 reads (14%) | catalogued as COSV53462254; called by muse, varscan2
- HBG2 | c.267G>A p.L89= | Silent (SNP) | VAF 41/366 reads (11%) | catalogued as COSV57962964; called by muse, mutect2, varscan2
- HDAC6 | c.1761C>T p.C587= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV61927529; called by muse, mutect2, varscan2
- HERC1 | c.11535C>T p.N3845= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV71245980; called by muse, mutect2
- HSD17B6 | c.795T>C p.T265= | Silent (SNP) | VAF 66/171 reads (39%) | catalogued as COSV59107137; called by muse, mutect2, varscan2
- HUWE1 | c.3120A>G p.P1040= | Silent (SNP) | VAF 111/581 reads (19%) | catalogued as COSV53335025; called by muse, mutect2, varscan2
- IGHV3-20 | c.75G>A p.E25= | Silent (SNP) | VAF 127/336 reads (38%) | catalogued as rs532591555; called by muse, mutect2, varscan2
- IGLV2-33 | c.225G>A p.R75= | Silent (SNP) | VAF 42/303 reads (14%) | catalogued as rs538913338; called by muse, mutect2, varscan2
- IPO13 | c.2853C>T p.C951= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs763227140, COSV54836279; called by muse, mutect2, varscan2
- ISL1 | c.549C>T p.R183= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1441983976; called by muse, mutect2
- ITGA11 | c.2004C>T p.C668= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as COSV59874979; called by muse, mutect2, varscan2
- JADE1 | c.1317T>G p.A439= | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as COSV56904078; called by muse, mutect2, varscan2
- JHY | c.390G>A p.P130= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs770027099, COSV56218061; called by muse, mutect2, varscan2
- KBTBD7 | c.498A>G p.R166= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs1162335338, COSV65266087; called by muse, mutect2, varscan2
- KCNC3 | c.1065C>T p.C355= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs761297836, COSV65386684; called by muse, mutect2, varscan2
- KDM1B | c.1257C>T p.G419= (on ENST00000449850; = p.G287= on NM_153042.4) | Silent (SNP) | VAF 29/319 reads (9%) | catalogued as COSV52808544; called by muse, mutect2
- KRTAP5-3 | c.588G>A p.Q196= | Silent (SNP) | VAF 215/625 reads (34%) | catalogued as COSV68790496; called by muse, mutect2, varscan2
- LBH | c.312G>A p.E104= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV68049131; called by muse, mutect2, varscan2
- LCE1B | c.318T>C p.C106= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV63980061; called by muse, mutect2
- LETMD1 | c.327T>C p.N109= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as COSV50396611; called by muse, mutect2
- LRP1 | c.1134C>T p.S378= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV54502362; called by muse, mutect2, varscan2
- LRP12 | c.165A>G p.R55= | Silent (SNP) | VAF 34/307 reads (11%) | catalogued as COSV52625747; called by muse, mutect2, varscan2
- LRP2 | c.9942C>A p.A3314= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as COSV55541296; called by muse, mutect2, varscan2
- LRP2 | c.9177C>T p.D3059= | Silent (SNP) | VAF 61/299 reads (20%) | catalogued as rs763193608, COSV55541313; called by muse, mutect2, varscan2
- MAGI1 | c.2832C>T p.G944= (on ENST00000402939 / NM_001033057.2; = p.G972= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs764888683, COSV58314845; called by muse, mutect2, varscan2
- MGA | c.951A>G p.S317= | Silent (SNP) | VAF 26/244 reads (11%) | catalogued as COSV54949069; called by muse, mutect2
- MGA | c.3021A>G p.K1007= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV54949078; called by muse, mutect2, varscan2
- MIGA2 | c.66C>A p.I22= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as COSV52975838; called by muse, mutect2
- MMP12 | c.321C>T p.P107= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs781783954; called by mutect2, varscan2
- MOGAT3 | c.951G>A p.T317= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs755711569, COSV56172752, COSV56175949; called by muse, mutect2, varscan2
- MOGS | c.1744C>T p.L582= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs563534545, COSV51968180; called by muse, mutect2, varscan2
- MPDZ | c.5871G>A p.Q1957= (on ENST00000319217 / NM_001330637.2; = p.Q1928= on NM_003829.5) | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV59915611; called by muse, mutect2, varscan2
- MRPL18 | c.129T>C p.A43= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV58457480; called by muse, mutect2, varscan2
- MSH6 | c.2694T>C p.P898= | Silent (SNP) | VAF 19/236 reads (8%) | catalogued as rs769668106, COSV52274594; ClinVar: likely benign; called by muse, mutect2
- MTMR14 | c.1224G>A p.L408= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs762967208, COSV56003312; called by muse, mutect2, varscan2
- MTMR2 | c.1002T>C p.G334= | Silent (SNP) | VAF 48/436 reads (11%) | catalogued as COSV60578545; called by muse, mutect2, varscan2
- MUC16 | c.30324A>G p.G10108= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as COSV67445625; called by muse, mutect2, varscan2
- MYEOV | c.87C>A p.P29= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV58293476; called by muse, mutect2, varscan2
- MYOG | c.369C>T p.R123= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV54095066; called by muse, mutect2, varscan2
- NAA20 | c.267T>C p.A89= | Silent (SNP) | VAF 86/432 reads (20%) | catalogued as COSV58548088; called by muse, mutect2, varscan2
- NAA40 | c.606C>T p.S202= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs371989301; called by muse, mutect2, varscan2
- NBPF11 | c.1965C>A p.P655= | Silent (SNP) | VAF 150/1385 reads (11%) | catalogued as rs1164740559; called by muse, mutect2, varscan2
- NCK2 | c.1129A>C p.R377= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV51888567; called by muse, mutect2
- NPEPPS | c.408T>G p.T136= | Silent (SNP) | VAF 14/264 reads (5%) | catalogued as COSV59100867; called by muse, mutect2
- NSD1 | c.1452A>G p.E484= | Silent (SNP) | VAF 64/195 reads (33%) | catalogued as rs1237773288, COSV61770956; called by muse, mutect2, varscan2
- NUP214 | c.1098C>T p.V366= | Silent (SNP) | VAF 100/259 reads (39%) | catalogued as rs761874142, COSV63907466; called by muse, mutect2, varscan2
- OR14A16 | c.240C>T p.I80= | Silent (SNP) | VAF 72/526 reads (14%) | catalogued as rs200580825, COSV62926143; called by muse, mutect2, varscan2
- OR4C3 | c.24A>G p.T8= | Silent (SNP) | VAF 96/291 reads (33%) | catalogued as rs761997175, COSV60583423; called by muse, mutect2, varscan2
- PCLO | c.13743A>G p.E4581= | Silent (SNP) | VAF 9/310 reads (3%) | catalogued as COSV61616601, COSV61634900; called by muse, mutect2
- PCNX1 | c.1206T>C p.S402= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as rs754054779, COSV53089384; called by muse, mutect2, varscan2
- PDE1C | c.12A>G p.P4= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV58503699; called by muse, mutect2
- PDSS2 | c.217C>T p.L73= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs778688092, COSV64646497; called by muse, mutect2
- PIK3CG | c.1860T>C p.S620= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV63245586; called by muse, mutect2, varscan2
- PIP5K1A | c.1644A>G p.T548= (on ENST00000368888 / NM_001135638.2; = p.T535= on NM_003557.3) | Silent (SNP) | VAF 63/726 reads (9%) | catalogued as COSV62957373; called by muse, mutect2
- PLA2G7 | c.495T>C p.I165= | Silent (SNP) | VAF 39/344 reads (11%) | catalogued as COSV51258440; called by muse, mutect2, varscan2
- PLCZ1 | c.1281T>C p.G427= | Silent (SNP) | VAF 91/285 reads (32%) | catalogued as COSV56848986; called by muse, mutect2, varscan2
- POMGNT2 | c.330G>A p.R110= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV60952669; called by muse, mutect2
- PPME1 | c.369T>C p.P123= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV60295678; called by muse, mutect2
- PPP1R2 | c.498T>C p.H166= | Silent (SNP) | VAF 46/804 reads (6%) | catalogued as COSV60497110; called by muse, mutect2
- PTPN11 | c.711T>C p.A237= | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as COSV61005551; called by muse, mutect2, varscan2
- RBM33 | c.822G>A p.R274= | Silent (SNP) | VAF 34/314 reads (11%) | catalogued as COSV56629172, COSV56635976; called by muse, mutect2, varscan2
- RNF4 | c.462C>T p.C154= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as rs760070877, COSV58640386; called by muse, mutect2, varscan2
- ROBO1 | c.4101G>A p.T1367= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as rs774597124, COSV71391840; called by muse, mutect2, varscan2
- RPS6KC1 | c.1272T>C p.P424= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV65297206; called by muse, mutect2, varscan2
- SCAP | c.1275G>A p.L425= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV55558961; called by muse, mutect2, varscan2
- SCN10A | c.1806T>C p.D602= | Silent (SNP) | VAF 43/265 reads (16%) | catalogued as COSV71860286; called by muse, mutect2, varscan2
- SEMG1 | c.474A>G p.Q158= | Silent (SNP) | VAF 83/240 reads (35%) | catalogued as COSV54871803; called by muse, varscan2
- SERPINE3 | c.1164T>C p.P388= | Silent (SNP) | VAF 28/288 reads (10%) | catalogued as COSV60876345; called by muse, mutect2
- SF3B2 | c.1791C>T p.F597= | Silent (SNP) | VAF 160/435 reads (37%) | catalogued as rs778816554, COSV59427013; called by muse, mutect2, varscan2
- SGCG | c.780C>T p.S260= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV54556125; called by muse, mutect2, varscan2
- SLC16A2 | c.1605T>C p.P535= | Silent (SNP) | VAF 63/249 reads (25%) | catalogued as COSV52082638; called by muse, mutect2, varscan2
- SLC22A14 | c.1278C>T p.C426= | Silent (SNP) | VAF 49/264 reads (19%) | catalogued as rs779440618, COSV56196633; called by muse, mutect2, varscan2
- SPAG17 | c.5907C>T p.S1969= | Silent (SNP) | VAF 48/330 reads (15%) | catalogued as rs1339095933, COSV60453151; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.699C>T p.H233= | Silent (SNP) | VAF 84/410 reads (20%) | catalogued as rs1212420117, COSV60321071; called by muse, mutect2, varscan2
- STXBP2 | c.1620C>T p.G540= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs374131788; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SVEP1 | c.1182C>T p.C394= | Silent (SNP) | VAF 184/580 reads (32%) | catalogued as COSV57029342; called by muse, mutect2, varscan2
- SYCP1 | c.1776T>C p.C592= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV65694635; called by muse, mutect2
- SYNE2 | c.4374T>C p.P1458= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59940055; called by muse, mutect2
- TENM4 | c.2028C>T p.G676= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as rs747289427, COSV53609426; called by muse, mutect2, varscan2
- TFCP2L1 | c.276C>T p.N92= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV55289143; called by muse, mutect2, varscan2
- TKFC | c.663C>T p.H221= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs767924731, COSV67523219; called by muse, mutect2, varscan2
- TMED8 | c.934C>T p.L312= | Silent (SNP) | VAF 35/380 reads (9%) | catalogued as COSV53625301; called by muse, mutect2
- TMEM64 | c.1047T>C p.S349= | Silent (SNP) | VAF 87/325 reads (27%) | catalogued as COSV69127576; called by muse, mutect2, varscan2
- TPO | c.1699C>T p.L567= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV61095138; called by muse, mutect2, varscan2
- TSGA10 | c.1173T>C p.D391= | Silent (SNP) | VAF 64/335 reads (19%) | catalogued as COSV61822076; called by muse, mutect2, varscan2
- TTBK2 | c.3579C>T p.S1193= | Silent (SNP) | VAF 104/512 reads (20%) | catalogued as COSV51157397; called by muse, varscan2
- TTN | c.16929A>G p.S5643= (on ENST00000591111; = p.S4716= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/187 reads (30%) | catalogued as COSV59893732; called by muse, mutect2, varscan2
- UNC45B | c.2256A>G p.K752= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as COSV52092350; called by muse, mutect2
- UNK | c.325C>T p.L109= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV53139431; called by muse, mutect2
- VIM | c.1131T>C p.A377= | Silent (SNP) | VAF 23/169 reads (14%) | catalogued as COSV56404744; called by muse, mutect2, varscan2
- ZUP1 | c.516T>C p.H172= | Silent (SNP) | VAF 86/218 reads (39%) | catalogued as COSV63943958; called by muse, mutect2, varscan2
- ASPDH | chr19:50514479 T>G | 5'Flank (SNP) | VAF 82/237 reads (35%) | catalogued as COSV65349237; called by muse, mutect2, varscan2
- ATP8B2 | c.1133+43C>T | Intron (SNP) | VAF 19/226 reads (8%) | catalogued as rs750823507, COSV59244751; called by muse, mutect2
- C7orf65 | n.248C>T | RNA (SNP) | VAF 46/129 reads (36%) | called by muse, mutect2, varscan2
- CARS1 | c.26-5623G>A | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs1055164486, COSV53455217; called by muse, mutect2
- CSAD | c.-90-648T>C | Intron (SNP) | VAF 16/92 reads (17%) | catalogued as COSV57241397; called by muse, varscan2
- DST | c.4297-4931A>G | Intron (SNP) | VAF 18/166 reads (11%) | catalogued as COSV54998293; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8252T>A | Intron (SNP) | VAF 21/73 reads (29%) | catalogued as COSV63387909; called by muse, mutect2, varscan2
- LIMK2 | c.1773-1335A>G | Intron (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53222975; called by muse, mutect2, varscan2
- LRP12 | chr8:104484423 A>G | 3'Flank (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- MIR507 | n.68del | RNA (DEL) | VAF 102/1046 reads (10%) | called by mutect2, pindel, varscan2
- NXT2 | chrX:109535929 A>G | 5'Flank (SNP) | VAF 36/352 reads (10%) | catalogued as COSV54296201; called by muse, varscan2
- RBM44 | c.-98-2335G>T | Intron (SNP) | VAF 5/79 reads (6%) | catalogued as COSV57627277; called by muse, mutect2
- RN7SL484P | chr15:99792414 G>A | 3'Flank (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2246G>A | Intron (SNP) | VAF 11/40 reads (28%) | catalogued as COSV61417530; called by muse, mutect2, varscan2
- TRPV2 | chr17:16441289 T>C | 3'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
